Surgical pathology report (de-identified scan), TCGA case TCGA-73-4670, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-73-4670-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT
*****Addendum*****

SPECIMEN(S): A. 4R LYMPH NODE
B. 4L LYMPH NODE
C. LEVEL 7 LYMPH NODE
D. 2R LYMPH NODE
E. 2L LYMPH NODE
F. LEVEL 5 LYMPH NODE
G. LEVEL 5 LYMPH NODE
H. LEVEL 6 LYMPH NODE
I. LEVEL 6 LYMPH NODE
J. LEFT UPPER LOBE

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

None given

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA-FSB-FSC: 4R, 4L, Level 7- No tumor seen. Diagnosis called to [redacted] at [redacted]

FSD-FSE: 2R LN-2L LN- No tumor seen. Diagnosis called to [redacted] at [redacted].

FSF, Level 5 lymph node, biopsy: No tumor cells identified

FSG, Level 5 lymph node, biopsy: No tumor cells identified

FSH, Level 6 lymph node, biopsy: No tumor cells identified

[page 2 of 6]
[REDACTED]

FSI, Level 6 lymph node, biopsy: No tumor cells identified, diagnoses called at [REDACTED]

[REDACTED]

GROSS DESCRIPTION:

A. 4R LYMPH NODE

Received fresh for frozen section are 4 pieces of tan pink soft tissue aggregating to 1.2 x 1.1 x 0.2 cm. Toto FSA.

B. 4L LYMPH NODE

Received fresh for frozen section are 2 pieces of tan pink soft tissue 0.6 x 0.2 x 0.1 cm and 0.3 x 0.2 x 0.2 cm. Toto FSB.

C. LEVEL 7 LYMPH NODE

Received fresh for frozen section are 3 pieces of tan pink soft tissue ranging from 0.5 x 0.4 x 0.2 cm to 0.2 x 0.2 x 0.2 cm. Toto FSC.

D. 2R LYMPH NODE

Received fresh for frozen section is a tan pink soft tissue fragment 1.2 x 1.1 x 0.2 cm. Toto FSD.

E. 2L LYMPH NODE

Received fresh for frozen section are 2 pieces of tan pink soft tissue 0.6 x 0.2 x 0.1 cm and 0.3 x 0.3 x 0.2 cm. Toto FSE.

F. LEVEL 5 LYMPH NODE

Received fresh labeled with the patient's identification and designated "level 5 lymph node" are multiple fragments of red-tan soft tissue measuring 1.5 x 1.2 x 0.3 cm in aggregate. Entirely submitted for frozen section, FSF.

G. LEVEL 5 LYMPH NODE

Received fresh labeled with the patient's identification and designated "level 5 lymph node" is a fragment of red-tan soft tissue measuring 1.6 x 1 x 0.6 cm. The specimen is bisected, entirely submitted for frozen section, FSG.

H. LEVEL 6 LYMPH NODE

Received fresh labeled with the patient's identification and designated "level 6 lymph node" is a fragment of red-tan soft tissue measuring 1.8 x 1 x 0.6 cm. The specimen is bisected, entirely submitted for frozen section, FSH.

I. LEVEL 6 LYMPH NODE

Received fresh labeled with the patient's identification and designated "level 6 lymph node" are two fragments of red-tan soft tissue measuring 0.5 x 0.3 x 0.2 cm in aggregate. Entirely submitted for frozen section, FSI.

[page 3 of 6]
J. LEFT UPPER LOBE

Received fresh is a 266g, 18 x 11 x 4.5 cm left upper lobectomy specimen. The pleural surface is red-purple, intact and remarkable for a palpable mass. This area is inked black. The bronchial margin is shaved and submitted in FSJ. Nine peri-bronchial lymph nodes are grossly identified ranging from 0.2 x 0.2 x 0.2 cm to 0.7 x 0.5 x 0.5 cm. The specimen is serially sectioned to reveal a 3.5 x 2.8 x 2.5 cm tan white firm mass with central necrosis, 2.2 cm from the bronchial margin and 0.1 cm from the pleural surface. The remaining lung parenchyma is grossly unremarkable. Representatively submitted:

FSJ: bronchial margin

J2-J5: mass with pleural surface

J6: 5 lymph nodes

J7: 4 lymph nodes

J8: uninvolved parenchyma

DIAGNOSIS:

A. LYMPH NODE, 4R, EXCISION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

B. LYMPH NODE, 4L, EXCISION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

C. LYMPH NODE, LEVEL 7, EXCISION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

D. LYMPH NODE, 2R, EXCISION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

E. LYMPH NODE, 2L, EXCISION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

F. LYMPH NODE, LEVEL 5, EXCISION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

G. LYMPH NODE, LEVEL 5, EXCISION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

H. LYMPH NODE, LEVEL 6, EXCISION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

I. LYMPH NODE, LEVEL 6, EXCISION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

[page 4 of 6]
J. LUNG, LEFT UPPER LOBE, LOBECTOMY:

- ADENOCARCINOMA, POORLY DIFFERENTIATED.
- 3.5 CM IN GREATEST DIMENSION.
- 2.8 X 2.5 CM IN ADDITIONAL DIMENSIONS.
- THE PLEURAL SURFACE IS NEGATIVE FOR TUMOR.
- THE BRONCHIAL MARGIN IS NEGATIVE FOR TUMOR.
- NO DEFINITE ANGIOLYMPHATIC INVASION IDENTIFIED.
- THE NON-NEOPLASTIC LUNG CONTAINS EMPHYSEMATOUS CHANGES.
- NO MALIGNANCY IDENTIFIED IN SIX PERIBRONCHIAL LYMPH NODES (0/6).

COMMENT: The tumor in this case is morphologically similar to the patient's previously diagnosed brain metastasis

SYNOPTIC REPORT - LUNG

Specimens Involved

Specimens: J: LEFT UPPER LOBE

Surgical Procedure: Lobectomy

Laterality: Left

Tumor Site: Upper lobe

Tumor Location: Peripheral

Tumor Size: Greatest diameter: 3.5cm
Additional dimensions: 2.8cm x 2.5cm

WHO CLASSIFICATION

Adenocarcinoma

Histologic Grade: G3: Poorly differentiated

Angiolymphatic Invasion: Absent

Bronchial Margins: Bronchial margins uninvolved

Tumor Distance from margin: 2.2cm

Visceral Pleural Involvement: Absent

Satellite Tumor(s): Absent

Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Negative 0 / 6

N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
Negative 0 / 7

N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular
Negative 0 / 2

Non-Neoplastic Lung: Atelectasis

Additional Pathologic Findings: None identified

Pathological Staging (pTNM): pT 2 N 0 M 1

Comment(s): Please see separate brain biopsy for metastasis.

[page 6 of 6]
ADDENDUM:

Frozen section result for specimen J was omitted from original report and is as follows:

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSJ: Left upper lobe, lobectomy: Bronchial margin is negative for tumor. Diagnosis called to

Source: NCI Genomic Data Commons file 129dcac2-74b2-46a4-834b-b3656189244f (TCGA-73-4670.A9349F65-0980-427E-AF86-1AF3C747926B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).